Gene-level copy-number profile of tumor specimen C3N-01192-05 from CPTAC case C3N-01192, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 60.1 years (21,957 days).
Specimen C3N-01192-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f1a21455-c24b-433f-ab27-e140686a2334.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01192-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/cbd83f55-7aba-4a77-8600-128426707e3d

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 47; copy number 1: 1; copy number 2: 5,572; copy number 3: 1,675; copy number 4: 41,559; copy number 5: 343; copy number 6: 9,175; copy number 7: 11; copy number 9: 18.

Homozygous deletions (total copy number 0; autosomes only): 47 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:232,697,299–233,013,256, 8 genes (within-gene range 0–2): GIGYF2, EEF1B2P7, AC064852.1, KCNJ13, RNU6-107P, Y_RNA, SNORC, NGEF.
- chr9:21,966,929–22,214,672, 9 genes (within-gene range 0–2): CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr17:31,094,927–31,382,116, 7 genes (within-gene range 0–2): NF1, AC079915.1, OMG, EVI2B, AC134669.1, EVI2A, AK4P1.
- chr22:31,676,256–32,205,001, 23 genes: PRR14L, DEPDC5, Z82190.2, RN7SL20P, AL022331.1, RNU6-201P, Z82190.1, C22orf24, YWHAH, AL008719.1, LINC02558, RN7SL305P, Z74021.1, SLC5A1, AP1B1P1, Z83839.1, AP1B1P2, Z83839.2, C22orf42, AL008723.1, AL008723.3, RFPL2, IGLCOR22-1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 18 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:12,891,160–13,117,567, 18 genes, copy number 9: GCDH, RPS6P25, SYCE2, MIR5695, FARSA, FARSA-AS1, CALR, MIR6515, AC092069.1, RAD23A, GADD45GIP1, DAND5, NFIX, AC138474.1, AC007787.1, AC007787.2, LYL1, TRMT1.

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
